Somatic mutation profile of tumor specimen TCGA-AA-A02K-01A (aliquot TCGA-AA-A02K-01A-21W-A096-10) from TCGA case TCGA-AA-A02K, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.7 years (18,506 days).
Specimen TCGA-AA-A02K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71b06549-fff5-4f30-9cc1-510b8b62466d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A02K-10A (Blood Derived Normal), aliquot TCGA-AA-A02K-10A-01W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f34a242f-2023-4b9a-9733-44755f9a8027

The open-access MAF lists 147 somatic variants for this specimen: 115 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 31, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 3, Frame Shift Ins 2, In Frame Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2309C>G p.S770* | Nonsense Mutation (SNP) | VAF 35/96 reads (36%) | catalogued as rs1060503310, CD941579, CM035803, COSV57394159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP250 | c.3463C>T p.R1155* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs749314857, CM146344, COSV100699053; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.8038C>T p.R2680C | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs794728283, CM930248, COSV100355798; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 36/204 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 104/232 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3073C>G p.P1025A (on ENST00000404938 / NM_001163941.2; = p.P580A on NM_178559.6) | Missense Mutation (SNP) | VAF 401/1584 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV51713565, COSV99328924; called by muse, mutect2, varscan2
- AC024598.1 | c.1294+2T>C p.X432_splice | Splice Site (SNP) | VAF 171/346 reads (49%) | catalogued as COSV100760407; called by muse, mutect2, varscan2
- ADAM23 | c.919A>G p.N307D | Missense Mutation (SNP) | VAF 111/307 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV52207576; called by muse, mutect2, varscan2
- ADCY2 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 273/1055 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs770402477, COSV57892241; called by muse, mutect2, varscan2
- ASXL3 | c.3020C>T p.P1007L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52456959; called by muse, mutect2, varscan2
- ATF2 | c.772G>T p.V258F | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV51367848, COSV51377629; called by muse, mutect2, varscan2
- BICD1 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as rs746325904, COSV55689057; called by muse, mutect2, varscan2
- C2CD5 | c.1984T>A p.S662T | Missense Mutation (SNP) | VAF 118/411 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as COSV61722744; called by muse, mutect2, varscan2
- C8orf34 | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 132/506 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57397003; called by muse, mutect2, varscan2
- CAMKK1 | c.599T>C p.I200T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs919206286, COSV99340416; called by muse, mutect2, varscan2
- CCDC54 | c.681T>G p.N227K | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV53757927, COSV99660272; called by muse, mutect2, varscan2
- CDC42BPG | c.2905G>A p.V969M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs199543708; called by muse, mutect2, varscan2
- CHD4 | c.3295T>C p.F1099L (on ENST00000357008 / NM_001363606.2; = p.F1112L on NM_001273.5) | Missense Mutation (SNP) | VAF 161/576 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58894723; called by muse, mutect2, varscan2
- CHUK | c.1519dup p.M507Nfs*17 | Frame Shift Ins (INS) | VAF 145/306 reads (47%) | catalogued as rs1564833034; called by mutect2, pindel, varscan2
- CNTNAP1 | c.3965C>T p.A1322V | Missense Mutation (SNP) | VAF 121/481 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs777298772, COSV52852263, COSV99226713; called by muse, mutect2, varscan2
- COL4A4 | c.4640C>T p.A1547V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780916516, COSV100307292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSO | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV101467867; called by muse, mutect2, varscan2
- CTSW | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327452; called by muse, mutect2, varscan2
- CYREN | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.367); catalogued as COSV51965550; called by muse, mutect2, varscan2
- DDI1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100159972; called by muse, mutect2, varscan2
- DENND5B | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 48/403 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as rs536783187, COSV100171797; called by muse, mutect2, varscan2
- DLGAP2 | c.2564C>T p.T855M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs749807967, COSV70104245; called by muse, mutect2
- DSC3 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 92/236 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776850837, COSV64571774; called by muse, mutect2, varscan2
- EFNA1 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs760965678, COSV100310417; called by muse, mutect2, varscan2
- EHD4 | c.1234G>C p.V412L | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99588145; called by muse, mutect2
- FAM110B | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.041); catalogued as COSV64064497; called by muse, mutect2, varscan2
- FAM71F2 | c.466C>A p.H156N | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101100710; called by muse, mutect2, varscan2
- FAM89A | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.041); catalogued as rs1558253161, COSV100792620; called by muse, mutect2, varscan2
- FDPS | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV100756249; called by muse, mutect2, varscan2
- FRS3 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756592782, COSV99442957; called by muse, mutect2, varscan2
- FSD1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0.108); catalogued as rs148882494; called by muse, mutect2, varscan2
- GJA10 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as COSV65355988, COSV65356146; called by muse, mutect2, varscan2
- HDAC1 | c.1402_1404del p.E468del | In Frame Del (DEL) | VAF 34/107 reads (32%) | catalogued as rs771427696; called by pindel, varscan2
- HLF | c.709A>G p.M237V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56828451; called by muse, mutect2, varscan2
- HNRNPF | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763741730, COSV61561510; called by muse, mutect2, varscan2
- IL12RB1 | c.1617C>T p.I539= | Splice Region (SNP) | VAF 29/60 reads (48%) | catalogued as rs778430238, COSV101651886; called by muse, mutect2, varscan2
- KCNA3 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs1204573283, COSV100871279; called by muse, mutect2
- KCNS2 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54640285; called by muse, mutect2, varscan2
- KIF20B | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.867); catalogued as COSV99590365; called by muse, mutect2, varscan2
- KLHL23 | c.1561G>T p.G521* | Nonsense Mutation (SNP) | VAF 181/551 reads (33%) | catalogued as COSV99775980; called by muse, mutect2, varscan2
- KPNA2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 37/375 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs782396125, COSV57856833; called by muse, mutect2, varscan2
- KRTAP22-1 | c.4A>C p.S2R | Missense Mutation (SNP) | VAF 82/265 reads (31%) | PolyPhen benign (0.305); catalogued as COSV58181909; called by muse, mutect2, varscan2
- LIG3 | c.1122C>G p.I374M | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.771); catalogued as COSV99252886; called by muse, mutect2, varscan2
- LYNX1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs753679195, COSV59990540; called by muse, mutect2, varscan2
- MAB21L2 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100462312; called by muse, mutect2, varscan2
- MAGEB18 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57464301; called by muse, mutect2, varscan2
- MARCHF10 | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100248372; called by muse, mutect2, varscan2
- MME | c.318C>A p.N106K | Missense Mutation (SNP) | VAF 69/389 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs756048894, COSV100852455; called by muse, mutect2, varscan2
- MOB3B | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.371); catalogued as COSV51774892; called by muse, mutect2, varscan2
- MPO | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1399823848, COSV99832857; called by muse, varscan2
- MPO | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as rs1476706511, COSV99832859; called by muse, mutect2, varscan2
- MRPS12 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359017039, COSV99671427; called by muse, mutect2, varscan2
- MTTP | c.2622C>A p.N874K | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99645388; called by muse, mutect2, varscan2
- NFATC2 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV65354569; called by muse, mutect2, varscan2
- NOL12 | c.335A>T p.D112V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100767115, COSV100767153; called by muse, mutect2, varscan2
- NPHP3 | c.3374G>A p.R1125Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs767752387, COSV100447091; called by muse, mutect2, varscan2
- NR1D1 | c.1751G>T p.R584L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.532); catalogued as rs775618097, COSV52840645; called by muse, mutect2, varscan2
- NSUN2 | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs201160646; called by muse, mutect2
- OR5H6 | c.736T>C p.S246P (on ENST00000642105; = p.S230P on NM_001005479.2) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101051796; called by muse, mutect2, varscan2
- PARP4 | c.592-2A>C p.X198_splice | Splice Site (SNP) | VAF 28/380 reads (7%) | catalogued as COSV101131807; called by muse, mutect2
- PCDHGB6 | c.2191C>G p.L731V | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV53897379, COSV99547551; called by muse, mutect2, varscan2
- PCSK9 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs776367625, COSV56161859; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- PDGFC | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV56852810; called by muse, mutect2, varscan2
- PIP5KL1 | c.670G>A p.E224K (on ENST00000388747 / NM_001135219.2; = p.E21K on NM_173492.1) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs1195377445, COSV100304898; called by muse, mutect2, varscan2
- PLCL1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV70876081; called by muse, mutect2
- PLEKHH2 | c.3237del p.K1079Nfs*10 | Frame Shift Del (DEL) | VAF 79/244 reads (32%) | catalogued as COSV99174925; called by mutect2, pindel, varscan2
- PLTP | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100819109; called by muse, mutect2, varscan2
- PRR11 | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV51874459; called by muse, mutect2, varscan2
- PTPRJ | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 56/346 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101395491; called by muse, mutect2, varscan2
- PTPRS | c.5650G>A p.V1884M | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759155627, COSV53613697; called by muse, mutect2, varscan2
- RGS9 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs1468415333, COSV52226788; called by muse, mutect2, varscan2
- RIMBP2 | c.2978A>G p.D993G | Missense Mutation (SNP) | VAF 110/321 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99899959; called by muse, mutect2, varscan2
- SBF1 | c.1637-2A>G p.X546_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100817901; called by mutect2, varscan2
- SCN2A | c.5360C>A p.A1787E | Missense Mutation (SNP) | VAF 113/432 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV51831993; called by muse, mutect2, varscan2
- SCN7A | c.5013A>C p.K1671N | Missense Mutation (SNP) | VAF 114/560 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV101313300; called by muse, mutect2, varscan2
- SDK1 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767615079, COSV101268801, COSV101269595; called by muse, mutect2, varscan2
- SLCO5A1 | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.223); catalogued as COSV52660324, COSV99480444; called by muse, mutect2, varscan2
- SSC4D | c.630G>T p.W210C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51881252; called by muse, varscan2
- SSTR3 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV60728593; called by muse, mutect2, varscan2
- SUPT6H | c.1440C>A p.N480K | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV100112584; called by muse, mutect2, varscan2
- SWI5 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 311/437 reads (71%) | catalogued as rs375393178; called by muse, mutect2, varscan2
- SYNE1 | c.22846C>T p.R7616W (on ENST00000367255 / NM_182961.4; = p.R7545W on NM_033071.3) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200236760; called by muse, mutect2, varscan2
- TAS1R2 | c.2287A>G p.T763A | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100946285; called by muse, mutect2, varscan2
- TBC1D8 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); catalogued as rs1312790159, COSV65209678, COSV65217506; called by muse, mutect2, varscan2
- TGS1 | c.2119C>G p.Q707E | Missense Mutation (SNP) | VAF 198/409 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52698069, COSV99485165; called by muse, mutect2, varscan2
- THBS4 | c.1278C>G p.N426K | Missense Mutation (SNP) | VAF 83/577 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as COSV100644354, COSV63470428; called by muse, mutect2, varscan2
- THSD7B | c.314A>G p.Q105R | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99754379; called by muse, mutect2, varscan2
- TMPRSS11E | c.410T>C p.I137T | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100542457; called by muse, mutect2, varscan2
- TOR3A | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1161315488, COSV100751246; called by muse, mutect2, varscan2
- TPO | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as rs753786141, COSV61103439; called by muse, mutect2
- TREH | c.336C>A p.S112R | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV99874628; called by muse, mutect2, varscan2
- TRPS1 | c.490A>T p.T164S (on ENST00000220888 / NM_001330599.2; = p.T177S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.262); catalogued as COSV55251292, COSV99632378; called by muse, mutect2, varscan2
- TRPT1 | c.544C>G p.P182A (on ENST00000317459 / NM_001160393.1; = p.P133A on NM_031472.4) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs778666111, COSV99655947; called by muse, mutect2, varscan2
- UGT2B28 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100158914, COSV59433651; called by muse, mutect2, varscan2
- VCL | c.2852C>G p.P951R | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated, low confidence (0.4); PolyPhen probably damaging (0.998); catalogued as rs368570586, COSV99280558; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- VIM | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV99813205; called by muse, mutect2, varscan2
- VWC2L | c.436C>A p.H146N | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.61); catalogued as COSV100435566; called by muse, mutect2
- WDR64 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100843890; called by muse, mutect2, varscan2
- XRCC1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs1345722388, COSV99486580; called by muse, mutect2, varscan2
- ZBED9 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 62/296 reads (21%) | catalogued as COSV101509331, COSV71729635; called by muse, mutect2, varscan2
- ZNF22 | c.334A>G p.K112E | Missense Mutation (SNP) | VAF 142/237 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV100026629; called by muse, mutect2, varscan2
- ZNF33B | c.1834A>C p.N612H | Missense Mutation (SNP) | VAF 32/315 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs565643232, COSV63943089; called by muse, mutect2
- ZNF626 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV101656995; called by muse, mutect2, varscan2
- ZNF629 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1316597740, COSV52700735; called by muse, mutect2, varscan2
- ZPBP2 | c.836G>A p.R279Q (on ENST00000348931 / NM_199321.3; = p.R257Q on NM_198844.3) | Missense Mutation (SNP) | VAF 104/629 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs141896432; called by muse, mutect2, varscan2
- ADAMTS20 | c.716dup p.N239Kfs*7 | Frame Shift Ins (INS) | VAF 72/402 reads (18%) | called by mutect2, pindel, varscan2
- APC | c.4592_4601del p.N1531Rfs*31 | Frame Shift Del (DEL) | VAF 32/202 reads (16%) | called by mutect2, pindel, varscan2
- C5 | c.4787_4788del p.S1596* | Frame Shift Del (DEL) | VAF 45/256 reads (18%) | called by pindel, varscan2
- HERC1 | c.6897_6898del p.C2300Hfs*14 | Frame Shift Del (DEL) | VAF 103/266 reads (39%) | called by mutect2, pindel, varscan2
- MED1 | c.2230del p.Q744Sfs*36 | Frame Shift Del (DEL) | VAF 433/805 reads (54%) | called by mutect2, pindel, varscan2
- ATP10A | c.792G>T p.L264= | Silent (SNP) | VAF 53/400 reads (13%) | catalogued as COSV100791246, COSV100791386; called by muse, mutect2, varscan2
- BPIFB6 | c.525C>T p.P175= | Silent (SNP) | VAF 232/540 reads (43%) | catalogued as rs770549260, COSV62755382; called by muse, mutect2, varscan2
- CDSN | c.534C>G p.T178= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as COSV99457019; called by muse, mutect2, varscan2
- CLIC6 | c.1464G>A p.P488= (on ENST00000360731 / NM_001317009.2; = p.P470= on NM_053277.3) | Silent (SNP) | VAF 227/785 reads (29%) | catalogued as rs115395599, COSV62447479; called by muse, mutect2, varscan2
- CNTN1 | c.1830G>T p.L610= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as COSV100751637, COSV100751864; called by muse, mutect2, varscan2
- DGAT2 | c.870C>T p.F290= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs959980779, COSV57175913; called by muse, mutect2, varscan2
- DYSF | c.2937G>A p.K979= | Silent (SNP) | VAF 32/159 reads (20%) | catalogued as rs1200679183, COSV99248830; called by muse, mutect2, varscan2
- FAM167B | c.63G>A p.G21= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV61108866; called by muse, mutect2, varscan2
- FGFR1 | c.1071C>T p.T357= (on ENST00000447712 / NM_023110.3; = p.T355= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 314/392 reads (80%) | catalogued as rs746072842, COSV58327471; called by muse, mutect2, varscan2
- FNDC1 | c.3633C>T p.G1211= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99794535, COSV99796574; called by muse, mutect2
- GKAP1 | c.786T>C p.L262= | Silent (SNP) | VAF 139/608 reads (23%) | catalogued as COSV64487264; called by muse, mutect2, varscan2
- H2AC15 | c.276G>A p.E92= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as rs753198609, COSV100357031; called by muse, mutect2, varscan2
- KALRN | c.1578G>A p.Q526= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1183403028, COSV99565737; called by muse, mutect2, varscan2
- KCNC1 | c.1437A>C p.P479= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99789482; called by muse, mutect2, varscan2
- MFSD6 | c.1641C>T p.H547= | Silent (SNP) | VAF 54/197 reads (27%) | catalogued as rs745816399, COSV99855282; called by muse, mutect2, varscan2
- MOGS | c.2253G>A p.R751= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99270636; called by muse, mutect2, varscan2
- MYCBP2 | c.10002A>G p.Q3334= (on ENST00000357337; = p.Q3372= on NM_015057.5) | Silent (SNP) | VAF 28/239 reads (12%) | catalogued as rs754880041, COSV62010001; called by muse, mutect2, varscan2
- NAMPT | c.777A>G p.K259= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as rs1247027908, COSV55994103; called by muse, mutect2, varscan2
- NEXMIF | c.2097A>G p.S699= | Silent (SNP) | VAF 44/237 reads (19%) | catalogued as COSV99280791; called by muse, mutect2, varscan2
- NIPBL | c.2505G>A p.G835= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV99241474; called by muse, mutect2, varscan2
- NRXN1 | c.4212C>T p.V1404= | Silent (SNP) | VAF 64/191 reads (34%) | catalogued as COSV60483934; called by muse, mutect2, varscan2
- OTUD4 | c.1995C>G p.L665= (on ENST00000447906 / NM_001366057.1; = p.L600= on NM_001102653.1) | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV101486022; called by muse, mutect2, varscan2
- PCDH11X | c.1170G>A p.A390= | Silent (SNP) | VAF 104/195 reads (53%) | catalogued as rs143117560, COSV100013090; called by muse, varscan2
- PCDHGA11 | c.438C>T p.H146= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV54046868; called by muse, varscan2
- PDE3A | c.1062C>T p.H354= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs773971834, COSV100762467; called by muse, mutect2, varscan2
- PRAMEF12 | c.1101C>T p.A367= | Silent (SNP) | VAF 59/135 reads (44%) | catalogued as rs1481315922, COSV63216157; called by muse, mutect2, varscan2
- PRPF8 | c.3915C>G p.S1305= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100517680; called by muse, mutect2, varscan2
- SULF2 | c.240C>T p.N80= | Silent (SNP) | VAF 50/660 reads (8%) | catalogued as rs774146908, COSV63415943; called by muse, mutect2
- TP63 | c.522G>A p.P174= | Silent (SNP) | VAF 40/258 reads (16%) | catalogued as rs780233345, COSV53205627, COSV53207672; called by mutect2, varscan2
- TSSK1B | c.633C>T p.C211= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs147355003; called by muse, mutect2, varscan2
- WDR48 | c.1191T>C p.D397= | Silent (SNP) | VAF 81/389 reads (21%) | catalogued as COSV100176748; called by muse, mutect2, varscan2
- MIR296 | n.30C>T | RNA (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
